HCMI case HCM-EXPT-0401-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/17264882-995a-4d9f-91dc-00de991f3ea0

Demographics
Sex at birth: female; Year of birth: 1952.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,118 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0401-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0401-C50-01A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 99; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-0401-C50-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 77; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 68; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
